TCGA case TCGA-06-0121 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital.
https://portal.gdc.cancer.gov/cases/0ff91707-190e-4e2d-a3a0-42e3207225e9

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 1.
  Slide TCGA-06-0121-01A-03-BS3: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 95; Percent stromal cells: 0.
  Slide TCGA-06-0121-01A-04-BS4: Section location: Bottom; Percent tumor cells: 1; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 60; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 90; Percent neutrophil infiltration: 0.
- Sample TCGA-06-0121-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
